Somatic mutation profile of cancer-model specimen HCM-CSHL-0382-C19-85N (3D Organoid, passage 4; aliquot HCM-CSHL-0382-C19-85N-01D-A905-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0382-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 68.0 years (24,847 days).
Specimen HCM-CSHL-0382-C19-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dee511a-ff9f-414d-a97d-fd7145512668.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0382-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0382-C19-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d41d3cbd-8520-43a5-bf4d-1e8b20f31a29

The open-access MAF lists 374 somatic variants for this specimen: 269 protein-altering or splice-affecting, 74 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 238, Silent 74, Nonsense Mutation 13, Intron 12, 5'UTR 8, Frame Shift Del 7, 3'UTR 7, Frame Shift Ins 4, Splice Site 3, RNA 3, Splice Region 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1263G>A p.W421* | Nonsense Mutation (SNP) | VAF 191/643 reads (30%) | catalogued as rs1554080106, CM083583, CX1110728, COSV57320574, COSV57364239; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 437/631 reads (69%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 514/517 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567555667, COSV52680942, COSV52985275; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC099489.1 | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 165/689 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs1185252826, COSV60864860; called by muse, mutect2, varscan2
- ACSBG1 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 147/550 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV51905547; called by muse, mutect2, varscan2
- ADGRB3 | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 337/524 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs113677156, COSV65405340; called by muse, mutect2, varscan2
- ATP7B | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 106/1009 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs1425712013; called by muse, mutect2, varscan2
- BCAR3 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 38/686 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759525792, COSV53075426; called by muse, mutect2
- BIVM-ERCC5 | c.4186G>T p.D1396Y | Missense Mutation (SNP) | VAF 301/1272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63244314; called by muse, mutect2, varscan2
- BTBD6 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 161/828 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.277); catalogued as rs1233759733; called by muse, mutect2, varscan2
- CCDC146 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 111/609 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); catalogued as COSV53549986; called by muse, mutect2, varscan2
- CHRNA4 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 1085/1988 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as rs150336658; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CHST15 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 280/754 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1281580042, COSV99068214; called by muse, mutect2, varscan2
- CILP2 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 286/1175 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1432117470, COSV52274243; called by muse, mutect2, varscan2
- CRYBG3 | c.3601G>A p.D1201N | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as rs1350154691; called by muse, mutect2
- CYB5R1 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 239/792 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs565157209; called by muse, mutect2, varscan2
- DCAF12L2 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 257/1285 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs772875857; called by muse, mutect2, varscan2
- DHX37 | c.2635G>A p.G879R | Missense Mutation (SNP) | VAF 307/944 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148208268; called by muse, mutect2, varscan2
- DLG2 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 208/841 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs146095353, COSV104381829; called by muse, mutect2, varscan2
- DMD | c.852G>C p.Q284H | Missense Mutation (SNP) | VAF 67/559 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); catalogued as COSV99920131; called by muse, mutect2, varscan2
- DNAH7 | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 77/643 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.195); catalogued as COSV56782722; called by muse, mutect2, varscan2
- DUSP11 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 209/1001 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1307552596; called by muse, mutect2, varscan2
- ECH1 | c.845C>G p.S282C | Missense Mutation (SNP) | VAF 100/1004 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55488529; called by muse, mutect2
- ESX1 | c.1040C>G p.P347R | Missense Mutation (SNP) | VAF 445/1188 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.915); catalogued as rs200088361, COSV65423956; called by muse, varscan2
- FAM236C | c.62C>G p.P21R | Missense Mutation (SNP) | VAF 89/820 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1476849384; called by muse, mutect2, varscan2
- FAM47A | c.1555T>C p.S519P | Missense Mutation (SNP) | VAF 143/760 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs867589029, COSV60496026; called by muse, varscan2
- FAM47A | c.1552C>G p.R518G | Missense Mutation (SNP) | VAF 144/760 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs17855514, COSV60495273, COSV60497171; called by muse, varscan2
- FAM47B | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 155/992 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1216086473, COSV100264456; called by muse, mutect2, varscan2
- FAM9A | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 200/947 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.193); catalogued as rs770415269; called by muse, mutect2, varscan2
- FER | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 54/538 reads (10%) | catalogued as rs1352925289, COSV99812314, COSV99812734; called by muse, mutect2, varscan2
- FGR | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 283/830 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64969815; called by muse, mutect2, varscan2
- FLG | c.9593T>G p.V3198G | Missense Mutation (SNP) | VAF 230/713 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs143183339; called by muse, mutect2, varscan2
- FLNC | c.4740C>A p.D1580E | Missense Mutation (SNP) | VAF 190/797 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759816924; called by muse, mutect2, varscan2
- FNBP4 | c.2908C>T p.R970W | Missense Mutation (SNP) | VAF 152/661 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs773342165; called by muse, mutect2, varscan2
- FNDC11 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 192/2124 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1425124388; called by muse, mutect2
- GIGYF1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 410/834 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV51943312; called by muse, mutect2
- GLTPD2 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 264/629 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs1298205138; called by muse, mutect2, varscan2
- GPHN | c.1690C>A p.R564S (on ENST00000315266 / NM_001377519.1; = p.R597S on NM_020806.5) | Missense Mutation (SNP) | VAF 239/379 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV104400759; called by muse, mutect2, varscan2
- GPR37 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 211/789 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as rs774806947, COSV58259643; called by muse, mutect2, varscan2
- GPRIN1 | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 496/923 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1445549801, COSV56134983; called by muse, mutect2, varscan2
- GZMK | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 123/403 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50244614; called by muse, mutect2, varscan2
- HYAL3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 255/748 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs377396269; called by muse, mutect2, varscan2
- ITIH1 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 232/367 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs774566520; called by muse, mutect2, varscan2
- KANK2 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 177/1102 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); catalogued as rs201796712; called by muse, mutect2, varscan2
- KCTD5 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 72/856 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs750284506; called by muse, mutect2
- LAMB1 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 71/477 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1417844287, COSV55970690; called by muse, mutect2, varscan2
- LCT | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 732/1135 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1017501359, COSV51555251, COSV99928905; called by muse, mutect2, varscan2
- LHX1 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 209/1085 reads (19%) | catalogued as rs752227729; called by muse, mutect2, varscan2
- LRP1B | c.4007C>T p.T1336I | Missense Mutation (SNP) | VAF 68/815 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs368584977; called by muse, mutect2
- LRP8 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 351/1135 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.313); catalogued as rs1216741308; called by muse, mutect2, varscan2
- MAGI2 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 240/865 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762159792, COSV62638508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MNDA | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 145/480 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.053); catalogued as rs1276427307, COSV63740837; called by muse, mutect2, varscan2
- MOGAT3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 248/461 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs139340331, COSV56175477; called by muse, mutect2, varscan2
- MRPL4 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 442/689 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302854853; called by muse, mutect2, varscan2
- MYBPC1 | c.1715G>A p.R572Q (on ENST00000550270 / NM_206820.2; = p.R597Q on NM_002465.4) | Missense Mutation (SNP) | VAF 214/496 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs149018411, COSV62252673; called by muse, mutect2, varscan2
- NBEA | c.8059G>A p.A2687T | Missense Mutation (SNP) | VAF 118/866 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as rs1009682064; called by muse, mutect2, varscan2
- NCKAP1L | c.2959A>G p.T987A | Missense Mutation (SNP) | VAF 80/325 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs757398054; called by muse, mutect2, varscan2
- OR10K1 | c.30A>T p.R10S | Missense Mutation (SNP) | VAF 151/507 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99193887; called by muse, mutect2, varscan2
- OR5M8 | c.193T>G p.L65V | Missense Mutation (SNP) | VAF 203/808 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59116733; called by muse, mutect2, varscan2
- OR8J1 | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 82/1222 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1488467758; called by muse, mutect2
- PCDHA7 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 689/1009 reads (68%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs782575776, COSV100971806, COSV65346027; called by muse, mutect2, varscan2
- PCDHGB5 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 497/899 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs756009874, COSV53966911; called by muse, mutect2, varscan2
- PCSK2 | c.1680G>T p.W560C | Missense Mutation (SNP) | VAF 116/1678 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99359615; called by muse, mutect2
- PINLYP | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 120/567 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1205824072, COSV99486409; called by muse, mutect2, varscan2
- PLEKHG4B | c.3448T>C p.C1150R (on ENST00000283426; = p.C1506R on NM_052909.5) | Missense Mutation (SNP) | VAF 231/678 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.125); catalogued as rs1382340179, COSV99359730; called by muse, mutect2
- PLN | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 396/667 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); catalogued as rs761056344, CM152289, COSV100682504, COSV62645794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPL | c.1125G>C p.E375D | Missense Mutation (SNP) | VAF 189/948 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV62046961; called by muse, mutect2, varscan2
- PSG4 | c.350C>G p.A117G | Missense Mutation (SNP) | VAF 117/568 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs1434408050; called by muse, mutect2, varscan2
- RAB38 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 268/583 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760114172, COSV54712089; called by muse, mutect2, varscan2
- RAF1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 170/741 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs906171410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAPGEF4 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 180/922 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51389637; called by muse, mutect2, varscan2
- RFTN1 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 202/902 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.311); catalogued as rs762244728; called by muse, mutect2, varscan2
- RILPL2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 172/1524 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.165); catalogued as rs1367873672, COSV99760304; called by muse, mutect2, varscan2
- RING1 | c.767C>A p.P256Q | Missense Mutation (SNP) | VAF 453/1096 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as rs1288256354; called by muse, mutect2, varscan2
- RNF148 | c.44C>G p.S15* | Nonsense Mutation (SNP) | VAF 56/700 reads (8%) | catalogued as COSV57353686; called by muse, mutect2
- ROBO1 | c.4577G>A p.G1526E | Missense Mutation (SNP) | VAF 184/607 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as rs772469243; called by muse, mutect2, varscan2
- ROBO2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 186/626 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778332221, COSV59906905; called by muse, mutect2, varscan2
- RPGRIP1L | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 106/646 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV50904448, COSV50910437; called by muse, mutect2, varscan2
- SAMD9 | c.4115del p.L1372Pfs*2 | Frame Shift Del (DEL) | VAF 125/604 reads (21%) | catalogued as COSV101180322; called by mutect2, pindel, varscan2
- SEC16A | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 221/622 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs1445008267; called by muse, mutect2, varscan2
- SGMS1 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 162/629 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV100693428; called by muse, mutect2, varscan2
- SLC16A14 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 382/916 reads (42%) | catalogued as COSV54621965; called by muse, mutect2, varscan2
- SLC17A6 | c.1158G>C p.K386N | Missense Mutation (SNP) | VAF 107/449 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99582527; called by muse, mutect2, varscan2
- SLC25A42 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 78/832 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59379930; called by muse, mutect2
- SLC6A20 | c.1067A>G p.K356R | Missense Mutation (SNP) | VAF 163/488 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs1359905244; called by muse, mutect2, varscan2
- SLC7A5 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 113/458 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs768321533; called by muse, mutect2, varscan2
- SMPDL3A | c.111A>G p.I37M | Missense Mutation (SNP) | VAF 196/583 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1234418516; called by muse, mutect2, varscan2
- SPAG17 | c.4806A>G p.I1602M | Missense Mutation (SNP) | VAF 108/325 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs758700968; called by muse, mutect2, varscan2
- SPTBN4 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 696/1437 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.216); catalogued as rs763945874; called by muse, mutect2, varscan2
- STAG3 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 103/635 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748067739; called by muse, mutect2, varscan2
- STARD13 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 70/706 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778437850, COSV99715474; called by muse, mutect2, varscan2
- SV2B | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 210/1293 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as rs150480705, COSV57700429; called by muse, mutect2, varscan2
- TBC1D17 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 149/743 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs117240064; called by muse, mutect2, varscan2
- TECRL | c.333C>T p.G111= | Splice Region (SNP) | VAF 82/278 reads (29%) | catalogued as rs535849187, COSV67085280; called by muse, mutect2, varscan2
- TECRL | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 53/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101168659; called by muse, mutect2, varscan2
- TECTA | c.3283C>T p.R1095C | Missense Mutation (SNP) | VAF 707/709 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as rs931887540; called by muse, mutect2, varscan2
- TMEM147 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 66/768 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV99383126; called by muse, mutect2
- TNXB | c.5093C>T p.P1698L (on ENST00000647633; = p.P1451L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 249/771 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771493330; called by muse, mutect2, varscan2
- TOR2A | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 430/664 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1239249032; called by muse, mutect2, varscan2
- TRIB3 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 75/1621 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs200611082, COSV53933040; called by muse, mutect2
- TTC4 | c.784del p.H262Mfs*5 | Frame Shift Del (DEL) | VAF 212/735 reads (29%) | catalogued as rs749113839, COSV64884432; called by mutect2, pindel, varscan2
- TTLL7 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 170/287 reads (59%) | catalogued as rs868019143; called by muse, mutect2, varscan2
- ZDBF2 | c.1064A>G p.E355G | Missense Mutation (SNP) | VAF 182/907 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as rs1332850093; called by muse, mutect2, varscan2
- ZMYM2 | c.3538C>T p.R1180* | Nonsense Mutation (SNP) | VAF 73/790 reads (9%) | catalogued as rs1247894077, COSV67035495; called by muse, mutect2
- ZNF407 | c.6081G>T p.E2027D | Missense Mutation (SNP) | VAF 296/472 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs779414301; called by muse, mutect2, varscan2
- ZNF516 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 179/455 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.106); catalogued as rs1480736202, COSV99069440; called by muse, mutect2, varscan2
- ZNF583 | c.864_865del p.R288Sfs*11 | Frame Shift Del (DEL) | VAF 196/1012 reads (19%) | catalogued as rs759925007; called by pindel, varscan2
- ZNF791 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 212/620 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs765211548; called by muse, mutect2, varscan2
- ABLIM1 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 159/633 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAN | c.2606A>T p.D869V | Missense Mutation (SNP) | VAF 208/1435 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ACOD1 | c.1019C>A p.A340D | Missense Mutation (SNP) | VAF 117/1635 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2
- ADAMTS5 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 284/1168 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS7 | c.1952G>T p.G651V | Missense Mutation (SNP) | VAF 278/1133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ADCY1 | c.907A>T p.S303C | Missense Mutation (SNP) | VAF 36/946 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2
- AHCTF1 | c.2815A>G p.N939D (on ENST00000366508; = p.N913D on NM_015446.5) | Missense Mutation (SNP) | VAF 27/694 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- AHNAK | c.11381A>T p.D3794V | Missense Mutation (SNP) | VAF 238/1077 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- AHNAK | c.11380G>A p.D3794N | Missense Mutation (SNP) | VAF 237/1075 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AKAP6 | c.6245C>G p.A2082G | Missense Mutation (SNP) | VAF 154/783 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2
- AKR1C2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ALAS2 | c.1061C>A p.T354N | Missense Mutation (SNP) | VAF 87/1185 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKRD18B | c.959C>G p.P320R | Missense Mutation (SNP) | VAF 69/596 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ANKRD30B | c.4042_4043insC p.N1348Tfs*2 | Frame Shift Ins (INS) | VAF 123/249 reads (49%) | called by mutect2, pindel, varscan2
- APBA3 | c.598del p.Y200Tfs*64 | Frame Shift Del (DEL) | VAF 423/820 reads (52%) | called by mutect2, pindel, varscan2
- ASPHD1 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 119/863 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ASXL3 | c.2141C>G p.S714* | Nonsense Mutation (SNP) | VAF 108/658 reads (16%) | called by muse, mutect2, varscan2
- ATP5PD | c.254_259del p.K85_Y86del | In Frame Del (DEL) | VAF 243/627 reads (39%) | called by mutect2, pindel, varscan2
- ATXN7 | c.2042G>T p.R681M | Missense Mutation (SNP) | VAF 86/731 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BARD1 | c.352A>T p.N118Y | Missense Mutation (SNP) | VAF 90/506 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CACNA1E | c.4962G>A p.M1654I | Missense Mutation (SNP) | VAF 168/492 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, varscan2
- CACNA1E | c.6436G>T p.V2146F (on ENST00000367573 / NM_001205293.3; = p.V2103F on NM_000721.4) | Missense Mutation (SNP) | VAF 404/636 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CADM2 | c.752A>T p.K251I (on ENST00000407528 / NM_001167674.2; = p.K253I on NM_153184.4) | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CCDC15 | c.1980C>A p.D660E | Missense Mutation (SNP) | VAF 259/432 reads (60%) | SIFT tolerated (0.52); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CCDC150 | c.676C>A p.L226I | Missense Mutation (SNP) | VAF 92/507 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH2 | c.137C>G p.S46W | Missense Mutation (SNP) | VAF 132/336 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- CFAP54 | c.7727A>C p.K2576T | Missense Mutation (SNP) | VAF 23/699 reads (3%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.636); called by muse, mutect2
- CLN3 | c.512G>C p.G171A (on ENST00000360019 / NM_001286104.2; = p.G195A on NM_000086.2) | Missense Mutation (SNP) | VAF 240/1014 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNDP2 | c.903G>T p.K301N | Missense Mutation (SNP) | VAF 215/216 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CNNM1 | c.975G>T p.W325C | Missense Mutation (SNP) | VAF 281/913 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CNTN1 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 178/644 reads (28%) | called by muse, mutect2, varscan2
- COL24A1 | c.3166G>T p.G1056C | Missense Mutation (SNP) | VAF 117/340 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL9A1 | c.1735C>A p.P579T | Missense Mutation (SNP) | VAF 299/509 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CPS1 | c.3067G>C p.D1023H | Missense Mutation (SNP) | VAF 55/906 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPSF1 | c.815C>G p.P272R | Missense Mutation (SNP) | VAF 92/1202 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2
- CSMD3 | c.3108T>G p.C1036W (on ENST00000297405 / NM_001363185.1; = p.C932W on NM_052900.3) | Missense Mutation (SNP) | VAF 141/832 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP2S1 | c.801C>G p.D267E | Missense Mutation (SNP) | VAF 423/844 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DCAF12L1 | c.965C>G p.A322G | Missense Mutation (SNP) | VAF 48/1034 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- DCHS1 | c.2767T>A p.S923T | Missense Mutation (SNP) | VAF 149/1010 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DLG1 | c.1469T>A p.F490Y | Missense Mutation (SNP) | VAF 147/570 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- DMD | c.7141G>T p.E2381* | Nonsense Mutation (SNP) | VAF 144/638 reads (23%) | called by muse, mutect2, varscan2
- DNAH5 | c.13149G>A p.M4383I | Missense Mutation (SNP) | VAF 268/396 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- EIF2AK3 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 144/572 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EMCN | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 251/400 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- EMX1 | c.127T>A p.F43I | Missense Mutation (SNP) | VAF 291/1336 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA7 | c.932A>C p.E311A | Missense Mutation (SNP) | VAF 228/678 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVC2 | c.1630C>G p.Q544E | Missense Mutation (SNP) | VAF 166/493 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- FAM236D | c.62C>G p.P21R (on ENST00000419795 / NM_001348203.1; = p.P17R on NM_001348202.1) | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- FAM9A | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 194/948 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC3B | c.3568T>A p.L1190M | Missense Mutation (SNP) | VAF 166/628 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- FOXP2 | c.1760A>T p.K587M | Missense Mutation (SNP) | VAF 96/279 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FRMD4A | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 417/989 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GABRA1 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 194/648 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- GIGYF1 | c.444C>G p.S148R | Missense Mutation (SNP) | VAF 416/846 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- GIPR | c.870C>A p.N290K | Missense Mutation (SNP) | VAF 64/698 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLI1 | c.627T>C p.D209= | Splice Region (SNP) | VAF 473/620 reads (76%) | called by muse, mutect2, varscan2
- GLI3 | c.368A>G p.H123R | Missense Mutation (SNP) | VAF 128/986 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- GLP1R | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 72/1092 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0.038); called by muse, mutect2
- GOLGA8M | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 36/353 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- GPX5 | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 20/754 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.046); called by muse, mutect2
- GRID2 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 157/514 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GTSF1L | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 120/1538 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- HNRNPCL1 | c.333G>T p.L111F | Missense Mutation (SNP) | VAF 44/1031 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.074); called by muse, mutect2
- HOXA3 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 90/1964 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2
- HOXA5 | c.502C>G p.P168A | Missense Mutation (SNP) | VAF 214/2670 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.011); called by muse, mutect2
- HOXB6 | c.338G>C p.S113T | Missense Mutation (SNP) | VAF 273/1173 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPA9 | c.1191G>C p.Q397H | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, mutect2
- HUWE1 | c.11414G>A p.R3805K | Missense Mutation (SNP) | VAF 82/984 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.815); called by muse, mutect2
- INKA1 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 488/766 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- INPP4B | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 165/247 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- INTS1 | c.1602G>C p.K534N | Missense Mutation (SNP) | VAF 145/1087 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IQSEC1 | c.1840C>T p.H614Y | Missense Mutation (SNP) | VAF 153/659 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- IRS1 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 628/922 reads (68%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, varscan2
- IRS2 | c.2457_2458dup p.S820Tfs*8 | Frame Shift Ins (INS) | VAF 230/1812 reads (13%) | called by mutect2, pindel, varscan2
- IRS4 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 179/816 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JAKMIP1 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 172/539 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- KIAA1755 | c.2681C>A p.A894D | Missense Mutation (SNP) | VAF 198/1151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRTAP13-1 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 227/902 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LAG3 | c.207-2_216del p.X69_splice | Splice Site (DEL) | VAF 277/888 reads (31%) | called by mutect2, varscan2
- LAMA1 | c.5026A>C p.T1676P | Missense Mutation (SNP) | VAF 89/315 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- LAX1 | c.44C>A p.T15N | Missense Mutation (SNP) | VAF 207/695 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LHX5 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 241/976 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- LOX | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 58/418 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- LRP1 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 116/765 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRPAP1 | c.309A>C p.E103D | Missense Mutation (SNP) | VAF 210/597 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC71 | c.899T>G p.L300R | Missense Mutation (SNP) | VAF 256/810 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- LRRFIP1 | c.1475_1511del p.T492Kfs*5 (on ENST00000392000 / NM_001137552.2; = p.T468Kfs*5 on NM_004735.4) | Frame Shift Del (DEL) | VAF 140/1264 reads (11%) | called by mutect2, pindel
- LRRIQ1 | c.2910T>A p.N970K | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- LVRN | c.2337A>C p.L779F | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MAP1B | c.6286G>T p.E2096* | Nonsense Mutation (SNP) | VAF 228/798 reads (29%) | called by muse, mutect2, varscan2
- MCM3 | c.854C>T p.S285F (on ENST00000229854 / NM_001366374.2; = p.S275F on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/702 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MED14 | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 601/783 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MINAR1 | c.1420G>T p.V474L | Missense Mutation (SNP) | VAF 252/903 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- MOV10 | c.1141-1G>T p.X381_splice | Splice Site (SNP) | VAF 112/326 reads (34%) | called by muse, mutect2, varscan2
- MYO1A | c.3031A>T p.S1011C | Missense Mutation (SNP) | VAF 162/642 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- NAV3 | c.5549A>G p.D1850G (on ENST00000397909 / NM_001024383.2; = p.D1828G on NM_014903.6) | Missense Mutation (SNP) | VAF 95/534 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCAM2 | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 284/634 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- NDE1 | c.395T>A p.I132N | Missense Mutation (SNP) | VAF 45/615 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- NFATC3 | c.2723C>G p.S908C | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); called by muse, mutect2
- NID2 | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 158/482 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLGN3 | c.1229G>A p.G410D (on ENST00000358741 / NM_181303.2; = p.G390D on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 230/1206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLGN4X | c.1567G>C p.V523L | Missense Mutation (SNP) | VAF 158/704 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- NOMO1 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 181/481 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NT5DC3 | c.1091T>C p.I364T | Missense Mutation (SNP) | VAF 155/556 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- NYX | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 153/1322 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- OASL | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 369/1031 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- OLAH | c.500C>A p.A167D (on ENST00000378228 / NM_001039702.3; = p.A220D on NM_018324.3) | Missense Mutation (SNP) | VAF 222/720 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- OSBPL6 | c.365C>A p.P122Q | Missense Mutation (SNP) | VAF 252/640 reads (39%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OTOGL | c.5065G>C p.D1689H (on ENST00000547103; = p.D1680H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/335 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OVCH1 | c.2894G>T p.S965I | Missense Mutation (SNP) | VAF 117/429 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- PARG | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 228/515 reads (44%) | called by muse, mutect2, varscan2
- PCDHB3 | c.2203C>A p.Q735K | Missense Mutation (SNP) | VAF 213/929 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PDCD11 | c.862G>T p.V288L | Missense Mutation (SNP) | VAF 47/430 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PDS5B | c.3623G>A p.R1208K | Missense Mutation (SNP) | VAF 38/738 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- POLR1A | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 201/633 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTGS2 | c.598C>A p.H200N | Missense Mutation (SNP) | VAF 88/537 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB14 | c.288_290del p.R96del | In Frame Del (DEL) | VAF 64/252 reads (25%) | called by pindel, varscan2
- RBBP6 | c.*2_*3del | Frame Shift Del (DEL) | VAF 81/298 reads (27%) | called by mutect2, pindel, varscan2
- RESF1 | c.3897del p.H1300Tfs*3 | Frame Shift Del (DEL) | VAF 179/686 reads (26%) | called by mutect2, pindel, varscan2
- RGMB | c.416G>A p.C139Y (on ENST00000513185 / NM_001366508.1; = p.C180Y on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 223/858 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF186 | c.387G>C p.L129F | Missense Mutation (SNP) | VAF 260/795 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ROBO2 | c.3225_3226insA p.P1076Tfs*25 | Frame Shift Ins (INS) | VAF 337/551 reads (61%) | called by mutect2, varscan2
- RPRD2 | c.2552A>C p.K851T | Missense Mutation (SNP) | VAF 160/583 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RXFP2 | c.2210T>C p.L737P | Missense Mutation (SNP) | VAF 103/912 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SCN1A | c.5918C>A p.T1973N (on ENST00000303395 / NM_001202435.3; = p.T1962N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/677 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCPEP1 | c.1183A>T p.S395C | Missense Mutation (SNP) | VAF 86/946 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.866); called by muse, mutect2
- SENP2 | c.436C>A p.L146M | Missense Mutation (SNP) | VAF 148/619 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SHANK2 | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 213/858 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC13A3 | c.724G>C p.A242P | Missense Mutation (SNP) | VAF 131/1186 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC17A9 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 182/1029 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC4A4 | c.1917A>G p.I639M (on ENST00000264485 / NM_001098484.3; = p.I595M on NM_003759.4) | Missense Mutation (SNP) | VAF 98/303 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLCO5A1 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 225/596 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SND1 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 238/1026 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- SPAG17 | c.3739G>T p.V1247F | Missense Mutation (SNP) | VAF 193/306 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA31E1 | c.2680T>G p.F894V | Missense Mutation (SNP) | VAF 457/689 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SPEG | c.3676C>G p.H1226D | Missense Mutation (SNP) | VAF 40/1100 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.062); called by muse, mutect2
- SUSD1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 192/601 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SYN3 | c.740T>A p.V247D | Missense Mutation (SNP) | VAF 98/764 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TLK1 | c.1429T>C p.Y477H | Missense Mutation (SNP) | VAF 23/567 reads (4%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.722); called by muse, mutect2
- TMEM94 | c.1001G>T p.W334L | Missense Mutation (SNP) | VAF 266/850 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNKS2 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 159/545 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TNR | c.2624T>C p.V875A | Missense Mutation (SNP) | VAF 294/461 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TNS1 | c.1371G>T p.M457I | Missense Mutation (SNP) | VAF 120/1511 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.139); called by muse, mutect2
- TTC37 | c.4028C>G p.S1343C | Missense Mutation (SNP) | VAF 48/519 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- TTN | c.69175C>A p.P23059T (on ENST00000591111; = p.P15635T on NM_003319.4) | Missense Mutation (SNP) | VAF 607/921 reads (66%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP9X | c.5538G>C p.L1846F | Missense Mutation (SNP) | VAF 182/824 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- VKORC1L1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 142/500 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- VRK3 | c.955C>A p.Q319K | Missense Mutation (SNP) | VAF 114/571 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- WBP1 | c.172+1G>T p.X58_splice | Splice Site (SNP) | VAF 103/640 reads (16%) | called by muse, mutect2, varscan2
- WDFY4 | c.5087G>T p.C1696F | Missense Mutation (SNP) | VAF 150/731 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBTB47 | c.1843A>C p.M615L | Missense Mutation (SNP) | VAF 357/554 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ZFHX4 | c.7322C>T p.A2441V | Missense Mutation (SNP) | VAF 239/1455 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZGRF1 | c.928A>T p.N310Y | Missense Mutation (SNP) | VAF 174/509 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ZIK1 | c.738dup p.A247Sfs*25 | Frame Shift Ins (INS) | VAF 380/1014 reads (37%) | called by mutect2, pindel, varscan2
- ZNF292 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 409/705 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF469 | c.3191A>G p.Y1064C (on ENST00000437464; = p.Y1092C on NM_001367624.2) | Missense Mutation (SNP) | VAF 77/588 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF658 | c.1790C>G p.T597R | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ZNF66 | c.743A>C p.K248T | Missense Mutation (SNP) | VAF 97/711 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF8 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 126/527 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF850 | c.1989T>G p.H663Q | Missense Mutation (SNP) | VAF 195/911 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF99 | c.943T>C p.C315R | Missense Mutation (SNP) | VAF 218/843 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA13 | c.10902C>A p.I3634= | Silent (SNP) | VAF 247/1418 reads (17%) | catalogued as COSV71293577; called by muse, mutect2, varscan2
- ACOD1 | c.1020C>A p.A340= | Silent (SNP) | VAF 114/1636 reads (7%) | called by muse, mutect2
- ADGRV1 | c.7263A>C p.P2421= | Silent (SNP) | VAF 198/731 reads (27%) | called by muse, mutect2, varscan2
- AGA | c.399C>G p.T133= | Silent (SNP) | VAF 103/323 reads (32%) | catalogued as COSV52806109; called by muse, mutect2, varscan2
- AKAP6 | c.6243G>T p.V2081= | Silent (SNP) | VAF 152/780 reads (19%) | called by muse, mutect2
- ALDH1L2 | c.2226C>T p.D742= | Silent (SNP) | VAF 248/518 reads (48%) | catalogued as rs781613297; called by muse, mutect2, varscan2
- ALPK1 | c.2881T>C p.L961= | Silent (SNP) | VAF 231/600 reads (39%) | catalogued as rs1258547718; called by muse, mutect2, varscan2
- ARAP1 | c.1329C>T p.R443= (on ENST00000393609 / NM_001040118.2; = p.R198= on NM_015242.4) | Silent (SNP) | VAF 436/949 reads (46%) | catalogued as rs975746779, COSV61993548; called by muse, mutect2, varscan2
- B3GALNT2 | c.666A>T p.T222= | Silent (SNP) | VAF 127/432 reads (29%) | called by muse, mutect2, varscan2
- C16orf96 | c.939G>A p.T313= | Silent (SNP) | VAF 118/1207 reads (10%) | catalogued as rs777259095; called by muse, mutect2
- CACNB2 | c.909G>T p.A303= (on ENST00000324631 / NM_201596.3; = p.A248= on NM_000724.4) | Silent (SNP) | VAF 240/426 reads (56%) | called by muse, mutect2, varscan2
- CFAP74 | c.3492C>T p.H1164= | Silent (SNP) | VAF 314/685 reads (46%) | catalogued as rs1330941752; called by muse, mutect2, varscan2
- CHST6 | c.606C>T p.R202= | Silent (SNP) | VAF 319/779 reads (41%) | catalogued as COSV104407867; called by muse, mutect2, varscan2
- CNTN6 | c.1134G>T p.V378= | Silent (SNP) | VAF 242/536 reads (45%) | called by muse, mutect2, varscan2
- CUX1 | c.2541C>T p.G847= | Silent (SNP) | VAF 157/973 reads (16%) | catalogued as rs375527499; called by muse, mutect2, varscan2
- DPP7 | c.279G>A p.E93= | Silent (SNP) | VAF 506/798 reads (63%) | catalogued as rs1361750987; called by muse, mutect2, varscan2
- EFCAB8 | c.1995C>T p.T665= | Silent (SNP) | VAF 250/1207 reads (21%) | catalogued as rs539746872; called by muse, mutect2, varscan2
- EHMT1 | c.3417C>T p.G1139= | Silent (SNP) | VAF 220/631 reads (35%) | catalogued as rs747339529; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHA2 | c.1587G>T p.P529= | Silent (SNP) | VAF 192/558 reads (34%) | called by muse, mutect2, varscan2
- EPHA6 | c.924G>A p.L308= | Silent (SNP) | VAF 337/662 reads (51%) | catalogued as COSV101064308, COSV67556607; called by muse, mutect2, varscan2
- EPPK1 | c.2377C>T p.L793= | Silent (SNP) | VAF 565/1518 reads (37%) | catalogued as COSV73261057; called by muse, mutect2, varscan2
- ERAP2 | c.2322C>T p.F774= | Silent (SNP) | VAF 281/514 reads (55%) | called by muse, mutect2, varscan2
- F5 | c.2949A>T p.G983= | Silent (SNP) | VAF 177/665 reads (27%) | called by muse, mutect2, varscan2
- FANCG | c.390C>T p.C130= | Silent (SNP) | VAF 711/1287 reads (55%) | catalogued as rs1489760268; called by muse, mutect2, varscan2
- FAT3 | c.9597T>G p.S3199= | Silent (SNP) | VAF 161/532 reads (30%) | called by muse, mutect2, varscan2
- FAT4 | c.1422C>A p.V474= | Silent (SNP) | VAF 149/457 reads (33%) | called by muse, mutect2, varscan2
- FKBP1B | c.273C>A p.V91= | Silent (SNP) | VAF 187/925 reads (20%) | called by muse, mutect2, varscan2
- GRHPR | c.525C>T p.F175= | Silent (SNP) | VAF 303/667 reads (45%) | catalogued as rs749885934, COSV58945798; called by muse, mutect2, varscan2
- GTF2IRD1 | c.621C>T p.G207= | Silent (SNP) | VAF 172/678 reads (25%) | catalogued as rs201574935; called by muse, mutect2, varscan2
- IGHV3-72 | c.111G>T p.L37= | Silent (SNP) | VAF 162/608 reads (27%) | called by muse, mutect2, varscan2
- IGKV3D-20 | c.87C>T p.A29= | Silent (SNP) | VAF 370/929 reads (40%) | called by muse, mutect2, varscan2
- IL26 | c.33G>A p.L11= | Silent (SNP) | VAF 80/524 reads (15%) | called by muse, mutect2, varscan2
- JMJD1C | c.4971G>A p.L1657= | Silent (SNP) | VAF 162/588 reads (28%) | called by muse, mutect2, varscan2
- KMT2D | c.1323G>T p.L441= | Silent (SNP) | VAF 501/1127 reads (44%) | called by muse, varscan2
- KRT1 | c.1920C>A p.S640= | Silent (SNP) | VAF 289/670 reads (43%) | catalogued as COSV52868110; called by muse, mutect2, varscan2
- LAMA1 | c.8611C>T p.L2871= | Silent (SNP) | VAF 199/588 reads (34%) | catalogued as rs1242283271; called by muse, mutect2, varscan2
- LRRC23 | c.408G>T p.L136= | Silent (SNP) | VAF 297/931 reads (32%) | called by muse, mutect2, varscan2
- MAD1L1 | c.1791G>A p.S597= | Silent (SNP) | VAF 150/1814 reads (8%) | catalogued as rs552747535; called by muse, mutect2
- MAGEB6B | c.918G>A p.E306= | Silent (SNP) | VAF 216/969 reads (22%) | called by muse, mutect2, varscan2
- MAP2K2 | c.903C>T p.P301= | Silent (SNP) | VAF 232/647 reads (36%) | catalogued as rs560316877; ClinVar: likely benign; called by muse, mutect2, varscan2
- MPST | c.453C>T p.P151= (on ENST00000341116 / NM_001369904.2; = p.P171= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 228/799 reads (29%) | catalogued as rs772514032; called by muse, mutect2, varscan2
- MTUS2 | c.1683C>T p.F561= | Silent (SNP) | VAF 310/1422 reads (22%) | catalogued as rs376749747; called by muse, mutect2, varscan2
- MYO15A | c.4632T>A p.T1544= | Silent (SNP) | VAF 69/483 reads (14%) | called by muse, mutect2, varscan2
- NFKBIZ | c.888A>T p.V296= | Silent (SNP) | VAF 200/609 reads (33%) | called by muse, mutect2, varscan2
- NKX2-8 | c.372G>T p.T124= | Silent (SNP) | VAF 284/1147 reads (25%) | catalogued as COSV99352369; called by muse, mutect2, varscan2
- NPIPB2 | c.1095A>G p.E365= (on ENST00000399147; = p.E225= on NM_001355514.1) | Silent (SNP) | VAF 92/696 reads (13%) | catalogued as rs79845530, COSV63638523; called by muse, varscan2
- P2RY13 | c.511T>C p.L171= | Silent (SNP) | VAF 290/636 reads (46%) | called by muse, mutect2, varscan2
- PCARE | c.2256C>T p.D752= | Silent (SNP) | VAF 636/1017 reads (63%) | catalogued as rs375644198; called by muse, mutect2, varscan2
- PJA1 | c.1548A>C p.G516= (on ENST00000361478 / NM_145119.4; = p.G328= on NM_022368.5) | Silent (SNP) | VAF 199/1207 reads (16%) | called by muse, mutect2, varscan2
- PKD1L1 | c.8061C>T p.P2687= | Silent (SNP) | VAF 191/2081 reads (9%) | catalogued as rs138774842; called by muse, mutect2
- PLA2R1 | c.175C>T p.L59= | Silent (SNP) | VAF 421/674 reads (62%) | catalogued as rs1165211630; called by muse, mutect2, varscan2
- PLEKHG2 | c.246G>A p.G82= | Silent (SNP) | VAF 180/1328 reads (14%) | called by muse, mutect2, varscan2
- PLOD2 | c.630C>T p.I210= | Silent (SNP) | VAF 59/448 reads (13%) | called by muse, mutect2, varscan2
- RYR2 | c.12084G>A p.S4028= | Silent (SNP) | VAF 143/465 reads (31%) | catalogued as rs751821960, COSV63682739, COSV63702754; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN10A | c.2457T>C p.N819= | Silent (SNP) | VAF 203/684 reads (30%) | called by muse, mutect2, varscan2
- SLC17A9 | c.1101C>T p.C367= | Silent (SNP) | VAF 625/1131 reads (55%) | catalogued as rs778254246; called by muse, mutect2, varscan2
- SLC32A1 | c.1569G>A p.A523= | Silent (SNP) | VAF 112/966 reads (12%) | called by muse, mutect2, varscan2
- SLC5A2 | c.1152G>A p.A384= | Silent (SNP) | VAF 389/727 reads (54%) | catalogued as CD035009, COSV57891854; called by muse, mutect2, varscan2
- SMIM10L2A | c.12G>A p.S4= | Silent (SNP) | VAF 161/694 reads (23%) | called by muse, mutect2, varscan2
- SPDYE3 | c.1335C>T p.F445= | Silent (SNP) | VAF 139/680 reads (20%) | called by muse, mutect2, varscan2
- SRPK3 | c.465C>T p.V155= | Silent (SNP) | VAF 258/754 reads (34%) | called by muse, mutect2, varscan2
- STRC | c.264G>A p.P88= | Silent (SNP) | VAF 54/122 reads (44%) | catalogued as rs1409559865; called by mutect2, varscan2
- TDRD15 | c.2418T>A p.A806= | Silent (SNP) | VAF 189/775 reads (24%) | called by muse, mutect2, varscan2
- TMTC1 | c.570C>A p.G190= (on ENST00000539277 / NM_001193451.2; = p.G82= on NM_175861.3) | Silent (SNP) | VAF 118/526 reads (22%) | called by muse, mutect2, varscan2
- TNR | c.3234C>T p.T1078= | Silent (SNP) | VAF 120/376 reads (32%) | catalogued as rs200777712, COSV54902159; called by muse, mutect2, varscan2
- TREML2 | c.321C>A p.R107= | Silent (SNP) | VAF 97/1210 reads (8%) | called by muse, mutect2
- USP1 | c.456A>G p.L152= | Silent (SNP) | VAF 136/495 reads (27%) | called by muse, mutect2, varscan2
- USP35 | c.336C>T p.P112= | Silent (SNP) | VAF 210/816 reads (26%) | catalogued as rs751787048; called by muse, mutect2, varscan2
- XIRP2 | c.9285T>G p.T3095= (on ENST00000628543; = p.T3270= on NM_152381.6) | Silent (SNP) | VAF 173/879 reads (20%) | called by muse, mutect2, varscan2
- ZAP70 | c.60C>T p.A20= | Silent (SNP) | VAF 465/1106 reads (42%) | catalogued as rs1204892323; called by muse, mutect2, varscan2
- ZBTB10 | c.588C>A p.G196= | Silent (SNP) | VAF 625/1569 reads (40%) | called by muse, mutect2, varscan2
- ZNF710 | c.1026G>T p.L342= | Silent (SNP) | VAF 224/1251 reads (18%) | called by muse, mutect2, varscan2
- ZNF81 | c.372A>G p.S124= | Silent (SNP) | VAF 82/632 reads (13%) | called by muse, mutect2, varscan2
- ZNF853 | c.972C>T p.L324= | Silent (SNP) | VAF 243/2002 reads (12%) | called by muse, mutect2, varscan2
- AC244394.2 | n.1233A>T | RNA (SNP) | VAF 151/479 reads (32%) | called by muse, mutect2, varscan2
- ACOXL | c.789-22007T>C | Intron (SNP) | VAF 153/697 reads (22%) | called by muse, mutect2, varscan2
- ADGRL4 | c.-9C>G | 5'UTR (SNP) | VAF 233/658 reads (35%) | catalogued as COSV100875692, COSV100875772; called by muse, mutect2, varscan2
- COMMD8 | c.*96C>A | 3'UTR (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- DNAJA4 | chr15:78264257 C>T | 5'Flank (SNP) | VAF 323/325 reads (99%) | catalogued as rs1315129556; called by muse, mutect2, varscan2
- DOCK7 | c.1801-1604_1801-1586del | Intron (DEL) | VAF 79/393 reads (20%) | called by mutect2, pindel, varscan2
- DUX4L8 | n.671C>T | RNA (SNP) | VAF 346/3122 reads (11%) | called by muse, varscan2
- EIPR1 | c.260-16908C>T | Intron (SNP) | VAF 170/828 reads (21%) | called by muse, mutect2, varscan2
- ELP4 | c.1040-18T>G | Intron (SNP) | VAF 95/317 reads (30%) | called by muse, mutect2, varscan2
- GNAS | c.970+44T>A | Intron (SNP) | VAF 23/254 reads (9%) | called by muse, mutect2
- GRPEL1 | c.-9G>C | 5'UTR (SNP) | VAF 179/622 reads (29%) | catalogued as rs370791021; called by muse, mutect2, varscan2
- KCTD1 | c.-15-47232A>T | Intron (SNP) | VAF 135/371 reads (36%) | called by muse, mutect2, varscan2
- KCTD7 | c.*1199T>C | 3'UTR (SNP) | VAF 105/456 reads (23%) | catalogued as rs1419949314; called by muse, mutect2, varscan2
- L3MBTL2 | c.-18T>A | 5'UTR (SNP) | VAF 152/452 reads (34%) | called by muse, mutect2, varscan2
- MED12 | c.*9G>A | 3'UTR (SNP) | VAF 224/889 reads (25%) | called by muse, mutect2, varscan2
- MRPL10 | c.52+40C>T | Intron (SNP) | VAF 308/652 reads (47%) | catalogued as rs1367693303; called by muse, mutect2, varscan2
- MYO1B | c.2557-10_2557-8del | Intron (DEL) | VAF 112/346 reads (32%) | called by pindel, varscan2
- NEBL | c.164+46335G>T | Intron (SNP) | VAF 175/677 reads (26%) | called by muse, mutect2, varscan2
- NEUROD1 | c.-6C>T | 5'UTR (SNP) | VAF 174/467 reads (37%) | called by muse, mutect2, varscan2
- NFATC2 | c.*110C>T | 3'UTR (SNP) | VAF 134/139 reads (96%) | catalogued as rs542710098, COSV65360154; called by muse, mutect2, varscan2
- NINJ2 | c.-118G>C | 5'UTR (SNP) | VAF 199/1023 reads (19%) | called by muse, mutect2, varscan2
- RPL28 | c.205+596A>C | Intron (SNP) | VAF 151/709 reads (21%) | called by muse, mutect2, varscan2
- TRIM53AP | n.536G>T | RNA (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- TTN | c.34354+405C>A | Intron (SNP) | VAF 54/525 reads (10%) | catalogued as rs1553780447; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBA3D | c.-48C>A | 5'UTR (SNP) | VAF 101/768 reads (13%) | catalogued as COSV100342950; called by muse, mutect2, varscan2
- UFL1 | c.-1del | 5'UTR (DEL) | VAF 146/615 reads (24%) | catalogued as COSV100990003, COSV100990082, COSV65149875; called by mutect2, pindel*, varscan2
- WDR45 | c.*102G>C | 3'UTR (SNP) | VAF 38/542 reads (7%) | catalogued as rs943051326, COSV59876297; called by muse, mutect2
- ZNF197 | c.*2331C>G | 3'UTR (SNP) | VAF 121/395 reads (31%) | called by muse, mutect2, varscan2
- ZNF646 | c.*1890C>T | 3'UTR (SNP) | VAF 51/312 reads (16%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3047G>T | Intron (SNP) | VAF 224/1029 reads (22%) | called by muse, mutect2, varscan2
- ZNF853 | c.-11G>C | 5'UTR (SNP) | VAF 212/1446 reads (15%) | catalogued as rs922792346, COSV101499538; called by muse, mutect2, varscan2
